Somatic mutation profile of tumor specimen MBCproject_0227_T1_WES (aliquot MBCproject_0227_T1_WES_1) from CMI case MBCproject_0227, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.2 years (16,155 days).
Specimen MBCproject_0227_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9edadb6c-1123-4a39-8204-0801c40240e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0227_SALIVA (Saliva), aliquot MBCproject_0227_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa60930e-ebcf-446b-ae41-cd9f2a0607ec

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, 5'Flank 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 108/247 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248104, COSV99031563; called by muse, mutect2, varscan2
- TP53 | c.613T>G p.Y205D | Missense Mutation (SNP) | VAF 120/271 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BRWD3 | c.4702C>T p.R1568W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs748635655, COSV100955730; called by muse, mutect2, varscan2
- CHRNA2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 141/255 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747493891, COSV99532384; called by muse, mutect2, varscan2
- KDM1A | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV56500216; called by muse, mutect2, varscan2
- RHOBTB2 | c.2119C>G p.P707A | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.096); catalogued as COSV52392241; called by muse, mutect2, varscan2
- SLC18A1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs372918747; called by muse, mutect2, varscan2
- TBX3 | c.886A>G p.N296D (on ENST00000257566 / NM_016569.4; = p.N276D on NM_005996.4) | Missense Mutation (SNP) | VAF 132/334 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV57469032, COSV57474113; called by muse, mutect2, varscan2
- THAP3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs547107923; called by muse, mutect2, varscan2
- ALG13 | c.1326+4del p.X442_splice | Splice Site (DEL) | VAF 25/101 reads (25%) | called by mutect2, pindel, varscan2
- AMIGO2 | c.1218_1219dup p.V407Afs*14 | Frame Shift Ins (INS) | VAF 31/152 reads (20%) | called by mutect2, pindel, varscan2
- COL6A2 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-73 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- KCTD9 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MAP1A | c.7810C>T p.R2604* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- MUC5B | c.6320C>A p.T2107N | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); called by mutect2, varscan2
- NEXMIF | c.730T>G p.C244G | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR6K2 | c.893T>A p.I298K | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- TBX1 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 220/505 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ZFHX4 | c.1511A>G p.N504S | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1 | c.3648C>G p.P1216= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as COSV54501339, COSV99675085; called by muse, mutect2, varscan2
- MAP2K3 | c.768C>A p.I256= (on ENST00000342679 / NM_145109.3; = p.I227= on NM_002756.4) | Silent (SNP) | VAF 58/245 reads (24%) | called by muse, mutect2, varscan2
- OR6K2 | c.219T>C p.Y73= | Silent (SNP) | VAF 83/214 reads (39%) | catalogued as rs1175372899; called by muse, mutect2, varscan2
- SLC16A4 | c.852G>C p.S284= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as COSV63917145; called by muse, mutect2, varscan2
- CDC14A | chr1:100351795 T>C | 5'Flank (SNP) | VAF 64/229 reads (28%) | called by muse, mutect2, varscan2
- FMR1 | c.-27C>T | 5'UTR (SNP) | VAF 129/457 reads (28%) | called by muse, mutect2, varscan2
- OAS3 | c.460+59_460+63dup | Intron (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
